Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6BE, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6BE-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

....

Clinical Diagnosis & History:
Retroperitoneal mass, likely sarcoma.

Specimens Submitted:

- 1: Radical resection left retroperitoneal left radical nephrectomy and left adrenalectomy
- 2: Spleen

DIAGNOSIS:

1. Retroperitoneum, left kidney and adrenal gland, mass, radical resection with left nephrectomy and adrenalectomy:
- Dedifferentiated Liposarcoma, in a background of well-differentiated liposarcoma.
- The tumor measures 21.0 cm in greatest dimension.
- The dedifferentiated component is a high grade spindle cell sarcoma.
- Well-differentiated Liposarcoma, lipoma-like and sclerosing type.
- Well-differentiated Liposarcoma component extends to the renal capsule but does not involve the renal parenchyma.
- Adrenal gland is uninvolved.
- Resection margins are uninvolved.
2. Spleen, splenectomy:
- Spleen (152 gm) with no significant pathologic changes.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1). The specimen is received fresh labeled, "radical resection, left retroperitoneal sarcoma, left radical nephrectomy and left adrenalectomy", and consists of a specimen of kidney, adrenal gland and a large, firm,

** Continued on next page **

ICD-3

Liposarcoma, dedifferentiated
8858/3

Site: Retroperitoneum
c48.0

JW 5/21/13

[page 2 of 3]
----- Page 2 of 3
tan/yellow well-circumscribed mass within the adipose tissue measuring in aggregate 42 x 29 x 8.5 cm. The kidney measures 12 x 5 x 2.5 cm. The attached ureter measures 7.0 cm in length and 0.2 cm in diameter. The ureter is not grossly associated with the mass. The attached renal vein measures 1.5 cm in length and 0.8 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified measuring 3.0 x 1.5 x 0.8 cm. There are multiple, well-circumscribed, tan/yellow masses measuring 21 x 10 x 6.5 cm in aggregate. The mass grossly does not infiltrate into the kidney. The mass is serially sectioned, revealing a partially tan/yellow myxoid cut-surface with other areas having a tan/white soft to firm cut-surface. The mass is enveloped by a thin fibrous tissue. Representative sections of the different areas of the mass are submitted for TPS and culture. Specimen photographs are taken. Representative sections are submitted.

Summary of sections:

UVA ureter, vein artery
A adrenal gland
WD well differentiated areas
MA myxoid areas
PD poorly differentiated areas
M margins
AK adipose tissue around the kidney
NK normal kidney
U ureter margin

2). The specimen is received in formalin labeled, "Spleen" and consists of a splenectomy specimen weighing 152 g and measuring 12.5 x 6.5 x 2.5 Cm. The splenic capsule is gray tan slightly nodular and glistening. Hilar area is markedly hemorrhagic and disrupted containing areas of blood clot. Hilar lymph nodes are grossly not identified. The specimen sectioned to reveal a glistening fleshy beefy red cut surface. Representative section submitted.

Summary of sections:

H-hilum (containing possible hilar vessels and nodes)
U-undesigned sectioning of the splenic parenchyma and capsule

Summary of Sections:

Part 1: Radical resection left retroperitoneal left radical nephrectomy and left adrenalectomy

Block	Sect.	Site	PCs	
1		ADRENAL		1
4		AK	4	
4		M	4	
5		MA	5	

** Continued on next page **

[page 3 of 3]
[REDACTED]

----- Page 3 of 3

1	NK	1
4	PD	4
1	U	1
1	UVA	1
4	WD	4

Part 2: Spleen

Block	Sect.	Site	PCs
2		H	2
5		u	5

** End of Report **

Criteria	lw 5/5/13	Yes	No
HIFAA Discrepancy			/

Source: NCI Genomic Data Commons file 45a9524b-6474-47d8-abaf-52e055cf3750 (TCGA-DX-A6BE.79C2249E-8408-4B50-9370-B4A19A713E7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).